Somatic mutation profile of tumor specimen TARGET-10-PARERM-09A (aliquot TARGET-10-PARERM-09A-01D) from TARGET case TARGET-10-PARERM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,289 days).
Specimen TARGET-10-PARERM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48100005-c973-4236-a87a-f3178e5401fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARERM-10A (Blood Derived Normal), aliquot TARGET-10-PARERM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85ea3c6f-c901-4d47-ba92-69f504876745

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, In Frame Del 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EFCAB1 | c.601G>A p.V201I | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1321361762; called by muse, mutect2, varscan2
- FAM133B | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs779150232, COSV101300194; called by mutect2, varscan2
- IL7R | c.724_736delinsCCTGGGAATT p.L242_S246delinsPGNC | In Frame Del (DEL) | VAF 19/69 reads (28%) | catalogued as COSV57406907; called by pindel, varscan2*
- NELL2 | c.208T>G p.S70A | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.71); PolyPhen benign (0.014); catalogued as rs775731500, COSV61571180; called by muse, mutect2, varscan2
- SHANK2 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as rs1218113600, COSV58330970; called by muse, mutect2
- FAM155B | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.365); called by muse, mutect2
- IER5 | c.941T>A p.L314Q | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- UMODL1 | c.1705G>A p.V569I | Missense Mutation (SNP) | VAF 41/138 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- CD7 | c.398-10dup | Intron (INS) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
